Gene-level copy-number profile of tumor specimen C3L-06413-02 from CPTAC case C3L-06413, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 84.1 years (30,703 days).
Specimen C3L-06413-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 115e607e-7d30-4df7-a5eb-e55250c5f743.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06413-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/1d67b2f8-4a5c-48ad-8ba3-46a9d34e8fbc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 4,709; copy number 2: 20,995; copy number 3: 27,612; copy number 4: 2,585; copy number 5: 2,658; copy number 6: 80; copy number 7: 207.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:66,093,431–66,094,909, 1 gene: NUFIP1P1.
- chr6:147,508,690–148,020,974, 5 genes: SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1.
- chr15:32,359,538–32,500,346, 13 genes: AC139426.2, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3.
- chr18:51,028,394–51,283,896, 4 genes (within-gene range 0–1): SMAD4, SRSF10P1, MEX3C, RNU1-46P.
- chr18:67,830,671–67,831,967, 1 gene (within-gene range 0–1): AC114689.2.
- chr19:36,687,612–36,772,825, 2 genes: ZNF567, ZNF850.
- chr21:14,108,813–14,210,891, 1 gene (within-gene range 0–1): LIPI.
- chr21:14,216,130–15,065,936, 16 genes (within-gene range 0–1): RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6.
- chr21:46,458,891–46,570,015, 3 genes: DIP2A, DIP2A-IT1, RNU6-396P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 207 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,271,566–47,042,350, 182 genes, copy number 7 (broad region; genes not listed).
- chr6:49,692,358–50,181,007, 13 genes, copy number 7: CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr10:54,486,230–54,656,051, 3 genes, copy number 7 (within-gene range 5–7): AL353784.1, NEFMP1, MIR548F1.
- chr21:12,999,676–13,427,773, 9 genes, copy number 7: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3.

Autosomal genes at a single copy (total copy number 1): 1,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
